Somatic mutation profile of tumor specimen 0DEFJX from CCDI case PBBPVL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 1.2 years (445 days).
Specimen 0DEFJX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf4f9cb5-36c3-46cd-9b7a-760e6cb735f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEFHO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e149e03-6ada-4b2e-b2aa-529bc3894f06

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPS1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 92/494 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs199969665, COSV100136150; called by muse, mutect2, varscan2
- PROX1 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 30/695 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868611779, COSV54776262; called by muse, mutect2
- EZH2 | c.1077C>G p.P359= (on ENST00000460911 / NM_001203247.2; = p.P364= on NM_004456.5) | Silent (SNP) | VAF 38/752 reads (5%) | called by muse, mutect2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- CEP43 | c.301-88G>A | Intron (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- PAAF1 | c.88+83G>C | Intron (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
